Gene-level copy-number profile of tumor specimen TCGA-CN-6018-01A from TCGA case TCGA-CN-6018, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 85.5 years (31,242 days).
Specimen TCGA-CN-6018-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.70de2092-30c5-4368-b336-0b0685a599c6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6018-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac6b960a-56a5-41c6-8f84-550051554b41

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,462; copy number 2: 24,010; copy number 3: 26,739; copy number 4: 2,634; copy number 5: 3,984; copy number 6: 161; copy number 7: 71; copy number 8: 344; copy number 9: 73; copy number 10: 88; copy number 11: 56; copy number 13: 8; copy number 14: 22; copy number 18: 125; copy number 22: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6018-01A-11D-1682-01): tumor purity 0.31, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–8): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr10:100,288,149–100,330,264, 1 gene (within-gene range 0–2): PKD2L1.
- chr11:44,656,771–44,656,920, 1 gene: AC104010.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 813 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:96,858,182–100,723,700, 151 genes, copy number 11–18 (broad region; genes not listed).
- chr8:29,333,064–32,911,598, 64 genes, copy number 13–22 (broad region; genes not listed).
- chr8:37,326,575–37,849,861, 18 genes, copy number 14: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2.
- chr8:37,858,949–37,861,333, 1 gene, copy number 14: AC130304.1.
- chr9:14,475–10,612,723, 149 genes, copy number 7–14 (within-gene range 1–14) (broad region; genes not listed).
- chr9:12,287,320–21,699,596, 148 genes, copy number 8–10 (broad region; genes not listed).
- chr9:21,811,621–21,812,347, 1 gene, copy number 8: TUBB8P1.
- chr9:21,994,139–22,128,103, 1 gene, copy number 8 (within-gene range 0–8): CDKN2B-AS1.
- chr9:22,046,758–29,318,952, 63 genes, copy number 7–8 (broad region; genes not listed).
- chr9:88,627,063–95,087,159, 144 genes, copy number 8 (broad region; genes not listed).
- chr9:95,113,708–95,123,868, 2 genes, copy number 8: AL354893.2, AL354893.1.
- chr18:24,725,762–29,048,719, 51 genes, copy number 7–10 (within-gene range 3–10): AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P.
- chr18:66,501,083–68,495,133, 20 genes, copy number 7 (within-gene range 2–7): CDH19, RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1, AC005909.2, LINC01912, AC022968.1.

Autosomal genes at a single copy (total copy number 1): 1,462. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
